Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A781, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A781-01A (Primary Tumor).

ICD-O-3

Astrocytoma, grade III 9401/3
C66CF

Site Brain, supratentorial NOS
C71.0

path
④ Brain, frontal lobe
C71.1

W 8/20/13

Case

Patient: **Age (years):** **Gender:** Female

Clinical diagnosis: Brain tumor

Date of procurement:

Sample:

Gross description:

The material presented by small gray pieces, about 4x2x1.5cm total from right frontal lobe

Microscopic description:

Received material is consistent with anaplastic astrocytoma, Ki67 – 8%.

Final diagnosis: Anaplastic astrocytoma: Grade III

Confidential

Criteria	W 8/13/13	Yes	No

Source: NCI Genomic Data Commons file 28ecb247-874a-4f1e-8fc6-7e3c218c4310 (TCGA-P5-A781.32064991-35D2-489F-836E-8646482DA73D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).